CCDI case PBBWZM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/948b05e0-b7f8-4a6a-86bf-f2b1e0f96aa1

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Liver; Age at diagnosis: 4.6 years (1,662 days).

Biospecimens (3 samples)
- Sample 0DJIKU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJIL5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJILR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
